FM case AD8211 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/82c08692-2c63-4cc3-88d7-b9312a8d28d3

Female, 49.5 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
